Gene-level copy-number profile of tumor specimen TCGA-HT-7604-01A from TCGA case TCGA-HT-7604, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 50.5 years (18,443 days).
Specimen TCGA-HT-7604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.7461d985-4511-4ef6-aeb2-83111b4afc5e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-7604-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af36af7b-29e5-4f3e-8f6b-ed2e91098669

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,013; copy number 2: 52,599; copy number 3: 2,367; copy number 4: 1,014; copy number 5: 625; copy number 6: 195.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-7604-01A-11D-2085-01): tumor purity 0.95, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 820 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:34,784,028–43,674,591, 195 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–17,709,867, 555 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:100,089,015–100,589,528, 9 genes, copy number 5 (within-gene range 3–5): PCCA, RPL15P18, AL356575.1, AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47.
- chr13:100,623,875–100,624,429, 1 gene, copy number 5: COX5BP6.
- chr13:112,485,011–114,337,626, 60 genes, copy number 5: TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.

Autosomal genes at a single copy (total copy number 1): 661. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
